Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A174, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A174-01A (Primary Tumor).

[page 1 of 6]
Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Site Code: Endometrium C54.1

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid type FIGO grade 3 (of 3) is identified forming a mass (2.6 x 1.9 x 1.4 cm) located in the fundus. No residual definitive serous papillary component is identified in the hysterectomy specimen. The tumor invades 0.2 cm into the myometrium (total myometrial thickness, 2.4 cm). The tumor does not involve the endocervix. The margins are negative for tumor. A single intramural leiomyoma (0.6 x 0.5 x 0.5 cm) is identified in the myometrium.

Seen in consultation with .

B. Ovary and fallopian tube, right, salpingo-oophorectomy: The right ovary is unremarkable. The right fallopian tube has multiple paratubal cysts (0.1 cm).

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (19) lymph nodes are negative for tumor.

D. Lymph nodes, left pelvic and lower para-aortic, lymphadenectomy: Multiple (9) lymph nodes are negative for tumor.

E. Ovary and fallopian tube, left, salpingo-oophorectomy: Negative for tumor.

F. Omentum, biopsy: Negative for tumor.

G. Small bowel, mesentery, biopsy: Negative for tumor.

H. Sigmoid colon, mesentery, biopsy: Negative for tumor.

[page 2 of 6]
I. Peritoneum, left pericolic gutter, biopsy: Negative for tumor.

J. Peritoneum, bladder, biopsy: Negative for tumor.

K. Peritoneum, left pelvic, biopsy: Negative for tumor.

L. Peritoneum, right pelvic, biopsy: Negative for tumor.

M. Peritoneum, right pericolic gutter, biopsy: Negative for tumor.

With available surgical material [AJCC pT1aN0] (7th edition, 2009).

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Uterus, hysterectomy: Endometrial adenocarcinoma, endometrioid, favor FIGO grade 2 (of 3). Hold to exclude minor serous component on permanent sections. Cervix is unremarkable. Myometrium shows a single (1) leiomyoma.

B. Ovary and fallopian tube, right, salpingo-oophorectomy: The right ovary is unremarkable. The right fallopian tube has multiple paratubal cysts (0.1 cm).

C. Lymph nodes, right pelvic, lymphadenectomy: Multiple (19) right pelvic lymph nodes are negative for tumor.

D. Lymph nodes, left pelvic and lower para-aortic, lymphadenectomy: Multiple (9) left pelvic lymph nodes are negative for tumor.

E. Ovary and fallopian tube, left, salpingo-oophorectomy: Negative for tumor.

F. Omentum, biopsy: Negative for tumor.

[page 3 of 6]
Hold over to process parts G through M on permanent sections.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus" is a 125.0 gram uterus with

unremarkable cervix. The uterine serosa is smooth. There is a 2.6

x 1.9 x 1.4 cm mass in the fundus of the endometrial cavity which

grossly appears to invade 0.2 cm into the 2.4 cm thick myometrium.

There is a single intramural leiomyoma (0.6 x 0.5 x 0.5 cm).

Representative sections are submitted.

B. Received fresh labeled "right salpingo-oophorectomy" is a 2.5 x

1.8 x 1.2 cm ovary with a 7.0 x 0.6 cm attached fallopian tube. The

ovary has a smooth outer surface with a solid cut surface.

Representative sections submitted.

C. Received fresh labeled "right pelvic lymph nodes" is a 4.5 x 4.5

x 1.7 cm aggregate of adipose tissue and lymph nodes.

Lymph nodes

submitted.

D. Received fresh labeled "left pelvic lymph nodes and lower para

aortic" is a 6.6 x 4.5 x 1.0 cm aggregate of adipose tissue and

lymph nodes. Lymph nodes submitted.

E. Received fresh labeled "left fallopian tube and ovary" is a 2.8

x 1.8 x 1.1 cm ovary with a 6.0 x 0.6 cm attached fallopian tube.

The ovary has a smooth outer surface with a solid cut surface.

Representative sections submitted.

F. Received fresh labeled "omental biopsy" is a 4.9 x 2.9 x 1.2 cm

[page 4 of 6]
portion of omentum. Lymph nodes are not identified.
Representative
sections are submitted.

G. Received fresh labeled "small bowel mesentery" is a
0.9 x 0.4 x
0.2 cm aggregate of yellow soft tissue which is entirely
submitted
for permanent sections only.

H. Received fresh labeled "sigmoid mesentery" is a 0.5 x
0.4 x 0.2
aggregate of yellow soft tissue which is entirely
submitted for
permanent sections only.

I. Received fresh labeled "left peri-colic gutter" is a
1.6 x 0.8 x
0.2 cm aggregate of yellow soft tissue which is entirely
submitted
for permanent sections only.

J. Received fresh labeled "bladder peritoneum" is a 1.6 x
0.6 x 0.2
cm aggregate of yellow soft tissue which is entirely
submitted for
permanent sections only.

K. Received fresh labeled "left pelvic peritoneum" is a
1.4 x 0.9 x
0.2 cm aggregate of yellow soft tissue which is entirely
submitted
for permanent sections only.

L. Received fresh labeled "right pelvic peritoneum" is a
0.6 x 0.4
x 0.2 cm aggregate of yellow soft tissue which is entirely
submitted
for permanent sections only.

M. Received fresh labeled "right peri-colic gutter" is a
1.4 x 0.9
x 0.2 cm aggregate of yellow soft tissue which is entirely
submitted. Grossed by

BLOCK SUMMARY:

Part A: Uterus

1 Cervix

[page 5 of 6]
- 2 Endometrial tumor-1
- 3 Endometrial tumor-2
- 4 Endometrial tumor-3
- 5 Fibroid
- 6 Endometrial tumor-4
- 7 Endometrial tumor-5
- 8 Endometrial tumor-6
- 9 Endometrial tumor-7

Part B: Right salpingo-oophorectomy

- 1 Rt ovary
- 2 Rt tube

Part C: Right Pelvic Lymph Nodes

- 1 Rt pelvic ln-1(C1)
- 2 Rt pelvic ln-1(C2)
- 3 Rt pelvic ln-1(C3)
- 4 Rt pelvic ln-1(C4)
- 5 Rt pelvic ln-4(C5)
- 6 Rt pelvic LNs 4 (C6)
- 7 Rt pelvic LNs 5 (C7)
- 8 Rt pelvic LNs 2 (C8)

Part D: Left Pelvic Lymph Nodes and left lower para-aortic lymph nodes

- 1 Lt pelvic ln-4(D1)
- 2 Lt pelvic ln-1(D2)
- 3 Lt pelvic ln-4(D3_)
- 4 Lt pelvic ln-1(D4)
- 5 Lt pelvic ln-1/2(D5)
- 6 Lt pelvic ln-2/2(D5)

Part E: Left Ovary and fallopian tube

- 1 Lt ovary
- 2 Lt tube

Part F: Omental biopsy

- 1 Omental biopsy

Part G: Small bowel mesentery

- 1 Sm bowel mesentary

Part H: Sigmoid mesentery

- 1 Sigmoid mesentary

Part I: Left peri-colic gutter

[page 6 of 6]
1 Lt peri-colic gutter

Part J: Bladder peritoneum
1 Bladder peritoneum

Part K: Left pelvic peritoneum
1 Lt pelvic peritoneum

Part L: Right pelvic peritoneum
1 Rt pelvic peritoneum

Part M: Right peri-colic gutter
1 Rt peri-colic gutter

Dual/Synchronous Pathology Noted		

Source: NCI Genomic Data Commons file dd3e0b5d-b367-4f41-bd9f-5e8ba12a71ee (TCGA-D1-A174.E45B2436-C0B2-44C3-B400-49C668114B01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).